Somatic mutation profile of cancer-model specimen HCM-BROD-0027-C34-85A (3D Neurosphere, passage 9; aliquot HCM-BROD-0027-C34-85A-01D-A786-36), derived from the metastatic tumor of HCMI case HCM-BROD-0027-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 65.4 years (23,897 days).
Specimen HCM-BROD-0027-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26ea113f-5c2d-4824-b7f2-d1a1e3eae905.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0027-C34-10A (Blood Derived Normal), aliquot HCM-BROD-0027-C34-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edfa82ce-dd80-41ef-95fa-fb0d9082a104

The open-access MAF lists 2,868 somatic variants for this specimen: 1,971 protein-altering or splice-affecting, 557 silent, 340 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,670, Silent 557, Intron 147, Nonsense Mutation 146, Frame Shift Del 66, RNA 60, 5'UTR 49, Splice Site 47, 3'UTR 39, 5'Flank 30, Splice Region 22, 3'Flank 15.

Variants (750 of 2,868; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 86/115 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 278/763 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1554309086; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs149229197; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- STK11 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 159/159 reads (100%) | hotspot (GDC flag); catalogued as rs1131690940, CM991157, COSV58820792; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 240/511 reads (47%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1129C>A p.P377T | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV50959538; called by muse, mutect2, varscan2
- ABCA4 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 199/284 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV64674465; called by muse, mutect2, varscan2
- ABCA8 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 70/128 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as rs1391761692, COSV52207765; called by muse, mutect2, varscan2
- ABCA9 | c.2860C>T p.P954S | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV100383519; called by muse, mutect2, varscan2
- ABCD1 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 98/191 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs889290843, CD011858, CM105292; called by muse, mutect2, varscan2
- AC018709.1 | c.191G>A p.C64Y | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.922); catalogued as rs770383744; called by muse, mutect2, varscan2
- ACADSB | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV100715195; called by muse, mutect2, varscan2
- ACAN | c.848C>A p.T283K | Missense Mutation (SNP) | VAF 100/210 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749047801, COSV100716994; called by muse, mutect2, varscan2
- ACAN | c.6404C>A p.A2135E | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100718317; called by muse, mutect2
- ACAN | c.6883G>T p.E2295* | Nonsense Mutation (SNP) | VAF 101/212 reads (48%) | catalogued as rs1334745093, COSV61357872; called by muse, mutect2, varscan2
- ACKR2 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs1022451688; called by muse, mutect2, varscan2
- ACSL4 | c.1417G>T p.G473C (on ENST00000340800 / NM_022977.2; = p.G432C on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61615123; called by muse, mutect2, varscan2
- ADAM29 | c.857C>A p.S286* | Nonsense Mutation (SNP) | VAF 9/11 reads (82%) | catalogued as COSV100822231, COSV63664359; called by muse, mutect2, varscan2
- ADAMTS16 | c.3026G>T p.R1009L | Missense Mutation (SNP) | VAF 181/339 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99068537, COSV99940840; called by muse, mutect2, varscan2
- ADAMTS2 | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 216/454 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51077696; called by muse, mutect2, varscan2
- ADAMTS6 | c.1310C>G p.A437G | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.46); catalogued as COSV66862422; called by muse, mutect2, varscan2
- ADGB | c.2173G>A p.G725S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV58857958; called by muse, mutect2, varscan2
- ADGRA1 | c.946C>A p.H316N | Missense Mutation (SNP) | VAF 259/411 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV63416446; called by muse, mutect2, varscan2
- ADGRG4 | c.1633T>C p.S545P | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99796053; called by muse, mutect2, varscan2
- ADGRV1 | c.10811C>T p.T3604I | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1228940279; called by muse, mutect2, varscan2
- AFAP1L2 | c.456C>A p.D152E | Missense Mutation (SNP) | VAF 97/334 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58415631; called by muse, mutect2, varscan2
- AFP | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as COSV56925041; called by muse, mutect2, varscan2
- AHNAK2 | c.11464A>G p.I3822V | Missense Mutation (SNP) | VAF 352/355 reads (99%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs779675075; called by muse, mutect2, varscan2
- AKAP14 | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57629397; called by muse, mutect2
- AKAP6 | c.5044G>A p.E1682K | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV55215860; called by muse, mutect2, varscan2
- ALDH7A1 | c.1093+1G>T p.X365_splice | Splice Site (SNP) | VAF 71/128 reads (55%) | catalogued as CS106148, COSV63160839; called by muse, mutect2, varscan2
- ALX1 | c.485G>C p.R162T | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57492123; called by muse, mutect2, varscan2
- ANKMY1 | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 166/318 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV56034837; called by muse, mutect2, varscan2
- ANKRD31 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV57163915; called by muse, mutect2
- ANKRD33B | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 204/390 reads (52%) | SIFT tolerated (0.59); PolyPhen benign (0.035); catalogued as COSV56978526; called by muse, mutect2, varscan2
- ANKRD36 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs768292033; called by muse, mutect2, varscan2
- ANO7 | c.959G>T p.W320L (on ENST00000274979; = p.W266L on NM_001370694.2) | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51469496; called by muse, mutect2, varscan2
- APBA2 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 79/150 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.297); catalogued as COSV68794051; called by muse, mutect2, varscan2
- AR | c.1705G>T p.G569W | Missense Mutation (SNP) | VAF 93/94 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555982864, CM942023, COSV101018580, COSV65965227; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF28 | c.1222A>T p.T408S | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs777570044; called by muse, mutect2, varscan2
- ARMC4 | c.2522G>C p.R841P | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV59462487; called by muse, mutect2, varscan2
- ASB10 | c.281G>C p.R94P | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as CM121521; called by muse, mutect2, varscan2
- ASPM | c.4978A>G p.I1660V | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs1279540274; called by muse, mutect2, varscan2
- ATP13A4 | c.2843-1G>C p.X948_splice | Splice Site (SNP) | VAF 64/134 reads (48%) | catalogued as COSV61317337; called by muse, mutect2, varscan2
- ATP2A1 | c.2661C>A p.D887E | Missense Mutation (SNP) | VAF 177/325 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV62869174; called by muse, mutect2, varscan2
- ATP2B4 | c.2936G>T p.R979L | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58181232; called by muse, mutect2, varscan2
- ATRNL1 | c.1712C>A p.P571Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV61801934, COSV61805324; called by muse, mutect2, varscan2
- B3GAT3 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 191/396 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as COSV99605846; called by muse, mutect2, varscan2
- BCORL1 | c.2723G>T p.C908F | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV54395122; called by muse, mutect2, varscan2
- BMS1 | c.3756G>T p.K1252N | Missense Mutation (SNP) | VAF 90/140 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65733691; called by muse, mutect2, varscan2
- BRAT1 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 162/297 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV100500692; called by muse, mutect2, varscan2
- BRINP1 | c.985C>A p.H329N | Missense Mutation (SNP) | VAF 225/308 reads (73%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.775); catalogued as COSV99775790; called by muse, mutect2, varscan2
- BRINP3 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.202); catalogued as COSV100818385, COSV66540992; called by muse, mutect2, varscan2
- BRIP1 | c.3342G>C p.Q1114H | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV52007379; called by muse, mutect2, varscan2
- BTNL2 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 84/154 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs1237317131; called by muse, mutect2, varscan2
- C7 | c.1373G>T p.R458L | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs369303619; called by muse, mutect2, varscan2
- C8orf33 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs571241836; called by muse, mutect2, varscan2
- CA10 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as COSV53342713; called by muse, mutect2, varscan2
- CACNA1F | c.1852C>A p.P618T | Missense Mutation (SNP) | VAF 147/323 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs782667611, COSV59903430; called by muse, mutect2, varscan2
- CACNA2D4 | c.2306G>A p.S769N | Missense Mutation (SNP) | VAF 70/269 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs1383838548; called by muse, varscan2
- CACNG5 | c.12C>A p.C4* | Nonsense Mutation (SNP) | VAF 62/109 reads (57%) | catalogued as rs138908277; called by muse, mutect2, varscan2
- CAMSAP2 | c.3890G>T p.G1297V (on ENST00000236925 / NM_001297707.2; = p.G1286V on NM_203459.3) | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.343); catalogued as COSV52667156; called by muse, mutect2, varscan2
- CAPN14 | c.1273T>A p.Y425N | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV104433194; called by muse, mutect2, varscan2
- CAPN14 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767915234; called by muse, mutect2, varscan2
- CAPN9 | c.615G>C p.E205D | Missense Mutation (SNP) | VAF 87/153 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99680251; called by muse, mutect2, varscan2
- CBFB | c.399+1G>T p.X133_splice | Splice Site (SNP) | VAF 47/73 reads (64%) | catalogued as COSV51998595, COSV52002396; called by muse, mutect2, varscan2
- CBLN1 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 100/282 reads (35%) | catalogued as COSV54654945; called by muse, mutect2, varscan2
- CCDC168 | c.17919C>A p.N5973K | Missense Mutation (SNP) | VAF 79/79 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as COSV59422514; called by muse, mutect2, varscan2
- CCDC39 | c.1722G>C p.M574I | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV56479520; called by muse, mutect2, varscan2
- CCDC39 | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.331); catalogued as rs1452983069, COSV56490167, COSV99870496; called by muse, mutect2, varscan2
- CCL4 | c.12C>G p.C4W | Missense Mutation (SNP) | VAF 153/353 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs199619169; called by muse, mutect2, varscan2
- CCNG2 | c.13G>T p.G5W | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); catalogued as rs1560421219; called by muse, mutect2, varscan2
- CCT8L2 | c.1157G>T p.R386L | Missense Mutation (SNP) | VAF 89/327 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.499); catalogued as COSV100743070; called by muse, mutect2, varscan2
- CD5L | c.868T>A p.S290T | Missense Mutation (SNP) | VAF 215/437 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV100941227; called by muse, mutect2, varscan2
- CDC73 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100813823; called by muse, mutect2, varscan2
- CDH11 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0.015); catalogued as COSV51752428; called by muse, varscan2
- CDH13 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51799039; called by muse, mutect2, varscan2
- CDK14 | c.947+1G>T p.X316_splice (on ENST00000380050 / NM_001287135.2; = p.X298_splice on NM_012395.3) | Splice Site (SNP) | VAF 41/101 reads (41%) | catalogued as COSV56033551, COSV56033914; called by muse, mutect2, varscan2
- CEACAM21 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 118/329 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781931004; called by muse, mutect2, varscan2
- CEACAM8 | c.614T>A p.V205D | Missense Mutation (SNP) | VAF 255/468 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754846441; called by muse, mutect2, varscan2
- CEP164 | c.2434G>T p.G812W | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV54037796; called by muse, mutect2
- CES4A | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 73/104 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV58653556, COSV58654966; called by muse, mutect2, varscan2
- CFAP47 | c.8117C>G p.P2706R | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV66218239; called by muse, mutect2, varscan2
- CHRNA4 | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 99/237 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs77345643; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CLDN17 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 135/136 reads (99%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV54523139; called by muse, varscan2
- CLDN2 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs377500294; called by muse, mutect2, varscan2
- CMIP | c.2156del p.C719Sfs*13 (on ENST00000537098 / NM_198390.2; = p.C625Sfs*13 on NM_030629.3) | Frame Shift Del (DEL) | VAF 48/160 reads (30%) | catalogued as COSV104432630; called by mutect2, pindel, varscan2
- CMTR2 | c.346T>C p.C116R | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100579318; called by muse, mutect2, varscan2
- CNGB3 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 115/267 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as COSV60691538; called by muse, mutect2, varscan2
- CNTNAP4 | c.835C>G p.R279G | Missense Mutation (SNP) | VAF 77/117 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV56670919; called by muse, mutect2, varscan2
- CNTNAP5 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs775327117, COSV70494830; called by muse, mutect2, varscan2
- CNTNAP5 | c.2805G>T p.L935F | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV70507425; called by muse, mutect2, varscan2
- COL11A1 | c.3856C>A p.P1286T | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV62175639; called by muse, mutect2, varscan2
- COL11A1 | c.907G>T p.V303F | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT tolerated (0.71); PolyPhen benign (0.308); catalogued as COSV62173608; called by muse, mutect2, varscan2
- COL11A1 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1312249178; called by muse, mutect2, varscan2
- COL16A1 | c.1620G>T p.R540S | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV54713504; called by muse, mutect2, varscan2
- COL22A1 | c.3817G>T p.G1273C | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57328946; called by muse, mutect2, varscan2
- COL3A1 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 94/204 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as rs1559056438; ClinVar: uncertain significance; called by muse, varscan2
- COL5A2 | c.3823C>T p.L1275F | Missense Mutation (SNP) | VAF 174/390 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs570175207; called by muse, mutect2, varscan2
- COL8A1 | c.1984T>A p.Y662N | Missense Mutation (SNP) | VAF 66/121 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs201189348; called by muse, mutect2, varscan2
- COL9A1 | c.1610C>A p.T537K | Missense Mutation (SNP) | VAF 145/309 reads (47%) | SIFT tolerated (0.77); PolyPhen benign (0.25); catalogued as COSV57888254; called by muse, mutect2, varscan2
- COL9A3 | c.700C>G p.R234G | Missense Mutation (SNP) | VAF 199/429 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs1027769042, COSV59650362; called by muse, mutect2, varscan2
- CPXM2 | c.1512G>T p.W504C | Missense Mutation (SNP) | VAF 180/283 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99582189; called by muse, mutect2, varscan2
- CR2 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 50/194 reads (26%) | catalogued as rs539720446; called by muse, mutect2, varscan2
- CRACD | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 132/222 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV51719576; called by muse, mutect2, varscan2
- CRAMP1 | c.3179C>T p.S1060L | Missense Mutation (SNP) | VAF 187/334 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs773981549; called by muse, mutect2, varscan2
- CREB3L2 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); catalogued as rs1352193617; called by muse, mutect2, varscan2
- CRIP3 | c.382G>T p.G128W | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV99240559; called by muse, mutect2, varscan2
- CRYBB2 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 141/252 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as CM111886; called by muse, mutect2
- CSMD1 | c.8830C>A p.R2944S (on ENST00000520002; = p.R2943S on NM_033225.6) | Missense Mutation (SNP) | VAF 86/146 reads (59%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.928); catalogued as COSV59318142; called by muse, varscan2
- CSMD3 | c.7777C>A p.R2593S (on ENST00000297405 / NM_001363185.1; = p.R2489S on NM_052900.3) | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV52164475, COSV52212859; called by muse, mutect2, varscan2
- CSMD3 | c.1987A>T p.S663C (on ENST00000297405 / NM_001363185.1; = p.S559C on NM_052900.3) | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV52307766; called by muse, mutect2, varscan2
- CTH | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61007360, COSV61007706; called by muse, mutect2, varscan2
- DACH1 | c.1761C>G p.D587E (on ENST00000619232 / NM_001366712.1; = p.D333E on NM_004392.6) | Missense Mutation (SNP) | VAF 57/57 reads (100%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.028); catalogued as COSV57520064; called by muse, mutect2, varscan2
- DACH1 | c.1427C>A p.P476Q (on ENST00000619232 / NM_001366712.1; = p.P424Q on NM_080759.6) | Missense Mutation (SNP) | VAF 46/48 reads (96%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.885); catalogued as COSV57518177; called by muse, mutect2, varscan2
- DACH2 | c.1303G>T p.G435W | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV64167402; called by muse, mutect2, varscan2
- DCLK3 | c.157C>G p.R53G | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV69362100, COSV69362635; called by muse, mutect2, varscan2
- DDX31 | c.2419G>T p.A807S | Missense Mutation (SNP) | VAF 124/521 reads (24%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.019); catalogued as rs751295139, COSV99707404; called by muse, mutect2, varscan2
- DDX41 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 204/414 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs11555633; called by muse, mutect2, varscan2
- DDX53 | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 22/22 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs769462069; called by muse, mutect2, varscan2
- DECR1 | c.999A>T p.K333N | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs15094; called by muse, mutect2, varscan2
- DEFB105A | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs759905858; called by mutect2, varscan2
- DENND2A | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 33/114 reads (29%) | catalogued as COSV52059599; called by muse, mutect2, varscan2
- DGKI | c.2600C>A p.P867Q | Missense Mutation (SNP) | VAF 110/184 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV55938146; called by muse, mutect2
- DGKK | c.1665G>C p.W555C | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65708764; called by muse, varscan2
- DLG2 | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV54687195; called by muse, mutect2, varscan2
- DLK1 | c.565G>T p.G189W | Missense Mutation (SNP) | VAF 125/128 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57990997; called by muse, varscan2
- DLX6 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 130/222 reads (59%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.824); catalogued as COSV50295543; called by muse, varscan2
- DMD | c.1292G>T p.W431L | Missense Mutation (SNP) | VAF 149/183 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM070909; called by muse, mutect2, varscan2
- DNAH3 | c.10735C>G p.Q3579E | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs757844714; called by muse, mutect2, varscan2
- DNAH9 | c.6134G>T p.R2045L | Missense Mutation (SNP) | VAF 70/127 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52358159; called by muse, mutect2, varscan2
- DNAI2 | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 196/437 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100209548; called by muse, mutect2, varscan2
- DNAJB13 | c.88A>T p.K30* | Nonsense Mutation (SNP) | VAF 131/214 reads (61%) | catalogued as rs1246467052; called by muse, mutect2, varscan2
- DNAJC1 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 185/395 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV65409674; called by muse, mutect2, varscan2
- DNMBP | c.3523G>T p.A1175S | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100143811; called by muse, mutect2, varscan2
- DOCK10 | c.2004C>A p.Y668* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV51425081; called by muse, mutect2, varscan2
- DOCK4 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 57/84 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs751288054; called by muse, mutect2, varscan2
- DPP6 | c.51G>T p.M17I | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.38); catalogued as rs781150778; ClinVar: uncertain significance; called by muse, varscan2
- DPP6 | c.1988G>T p.R663L (on ENST00000377770 / NM_001364500.2; = p.R601L on NM_001936.5) | Missense Mutation (SNP) | VAF 127/184 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59643903; called by muse, mutect2, varscan2
- DPY19L2 | c.2186C>A p.P729H | Missense Mutation (SNP) | VAF 137/280 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV100192734; called by muse, mutect2, varscan2
- DPY19L2 | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as rs1220779082, COSV100116657; called by muse, mutect2, varscan2
- DUOXA2 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 261/530 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1021093996; called by muse, mutect2, varscan2
- DVL1 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 125/474 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs944936291; called by muse, mutect2, varscan2
- DYSF | c.2690C>T p.T897M | Missense Mutation (SNP) | VAF 130/337 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs769739410, COSV99249939; ClinVar: uncertain significance; called by muse, varscan2
- EGR4 | c.853G>A p.V285I (on ENST00000545030; = p.V182I on NM_001965.4) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs564426644; called by muse, mutect2, varscan2
- ELAVL4 | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV100836952; called by muse, mutect2, varscan2
- ELOVL7 | c.473G>A p.W158* | Nonsense Mutation (SNP) | VAF 78/131 reads (60%) | catalogued as rs768134267; called by muse, mutect2, varscan2
- EMILIN1 | c.1816C>A p.L606M | Missense Mutation (SNP) | VAF 142/586 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV53155866, COSV53155993; called by muse, mutect2, varscan2
- EOLA2 | c.429C>A p.F143L | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV100778095; called by muse, mutect2, varscan2
- EPB41L5 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55348550; called by muse, mutect2, varscan2
- EPHA6 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1374125907, COSV101063111, COSV67585991; called by muse, mutect2, varscan2
- EPS8L1 | c.1471G>T p.A491S (on ENST00000201647 / NM_133180.3; = p.A364S on NM_017729.3) | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52379833; called by muse, mutect2, varscan2
- EPYC | c.722A>G p.H241R | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.288); catalogued as rs758118677; called by muse, mutect2, varscan2
- ERICH6 | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs753770853, COSV55798938; called by muse, varscan2
- ESCO1 | c.1200C>G p.N400K | Missense Mutation (SNP) | VAF 49/66 reads (74%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs757551403; called by muse, mutect2, varscan2
- ESR2 | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 146/147 reads (99%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV50833200; called by muse, mutect2, varscan2
- ESRP1 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344070630, COSV64412266; called by muse, mutect2, varscan2
- ESRRB | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 165/165 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV99835126; called by muse, mutect2, varscan2
- EXT2 | c.5G>T p.C2F (on ENST00000343631; = p.C35F on NM_000401.3) | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.035); catalogued as rs1565196088; called by muse, mutect2, varscan2
- F11 | c.1334A>T p.Y445F | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as CM995127; called by muse, mutect2, varscan2
- F8 | c.4863C>A p.N1621K | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV64273136; called by muse, mutect2, varscan2
- FAM102A | c.988G>T p.V330L (on ENST00000373095 / NM_001035254.3; = p.V188L on NM_203305.2) | Missense Mutation (SNP) | VAF 198/262 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100305597; called by muse, mutect2
- FAM104A | c.41C>T p.T14M | Missense Mutation (SNP) | VAF 119/276 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as rs749798858; called by muse, mutect2, varscan2
- FAM170A | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58925088, COSV58925339; called by muse, mutect2, varscan2
- FAM227B | c.1007C>A p.S336* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV100174813; called by muse, mutect2
- FAM71F2 | c.229G>C p.V77L | Missense Mutation (SNP) | VAF 256/540 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV66352411; called by muse, mutect2
- FAM83B | c.2786C>A p.T929N | Missense Mutation (SNP) | VAF 68/108 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV60920191; called by muse, mutect2, varscan2
- FAT3 | c.9713G>C p.R3238T | Missense Mutation (SNP) | VAF 162/267 reads (61%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); catalogued as COSV53132527; called by muse, mutect2, varscan2
- FBLN7 | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 138/324 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99735000; called by muse, mutect2, varscan2
- FBXO38 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV57030219; called by muse, mutect2, varscan2
- FBXO38 | c.1859G>T p.R620L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as COSV57026710; called by muse, mutect2, varscan2
- FBXO40 | c.301C>A p.R101S | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57522667; called by muse, mutect2, varscan2
- FBXO40 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57524889; called by muse, mutect2, varscan2
- FBXW7 | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.069); catalogued as COSV99898738, COSV99900887; called by muse, mutect2, varscan2
- FBXW8 | c.563C>T p.P188L (on ENST00000309909; = p.P226L on NM_012174.1) | Missense Mutation (SNP) | VAF 87/153 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.843); catalogued as rs1175677041, COSV59302564, COSV99997913; called by muse, mutect2, varscan2
- FCHO1 | c.829C>A p.Q277K | Missense Mutation (SNP) | VAF 163/163 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as rs749294013; called by muse, mutect2, varscan2
- FER1L6 | c.2546C>A p.P849H | Missense Mutation (SNP) | VAF 120/207 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101205212; called by muse, mutect2, varscan2
- FGB | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 65/105 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100122258; called by muse, mutect2, varscan2
- FGFBP3 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 138/438 reads (32%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs200280119; called by muse, mutect2, varscan2
- FLG | c.8498G>A p.G2833E | Missense Mutation (SNP) | VAF 300/979 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs1401517481, COSV64246918; called by muse, mutect2, varscan2
- FLG | c.6181G>C p.A2061P | Missense Mutation (SNP) | VAF 306/638 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.441); catalogued as rs1245044789; called by muse, mutect2, varscan2
- FLG | c.5650C>A p.R1884S | Missense Mutation (SNP) | VAF 332/700 reads (47%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.719); catalogued as COSV64242050; called by muse, mutect2, varscan2
- FLG2 | c.5684C>A p.T1895K | Missense Mutation (SNP) | VAF 135/289 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as rs1305913928; called by muse, mutect2, varscan2
- FMN2 | c.3413C>A p.A1138E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs199570117; called by muse, varscan2
- FMR1 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 56/133 reads (42%) | catalogued as COSV54424364; called by muse, mutect2, varscan2
- FSCB | c.343G>T p.V115L | Missense Mutation (SNP) | VAF 41/41 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV61217816; called by muse, mutect2, varscan2
- FSCB | c.59C>G p.P20R | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs572138282; called by muse, mutect2, varscan2
- FSCN3 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs751230329; called by muse, mutect2, varscan2
- FUT6 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 265/266 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747596068; called by muse, mutect2, varscan2
- FUT8 | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 83/83 reads (100%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV61289334; called by muse, mutect2, varscan2
- GABRB3 | c.88G>C p.G30R | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV59483112; called by muse, mutect2, varscan2
- GABRR1 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.911); catalogued as rs1562298617, COSV101034070, COSV65619209; called by muse, mutect2, varscan2
- GAGE1 | c.332-1G>T p.X111_splice | Splice Site (SNP) | VAF 40/82 reads (49%) | catalogued as rs373465046; called by muse, mutect2, varscan2
- GALC | c.1671-2A>T p.X557_splice | Splice Site (SNP) | VAF 47/47 reads (100%) | catalogued as CS162996, COSV54331432; called by muse, mutect2, varscan2
- GAS2L2 | c.1753G>A p.G585R | Missense Mutation (SNP) | VAF 186/379 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs782648695; called by muse, mutect2, varscan2
- GATA4 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as rs1243318122; called by muse, mutect2, varscan2
- GBX1 | c.1062C>A p.H354Q | Missense Mutation (SNP) | VAF 94/164 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs1335748337; called by mutect2, varscan2
- GCN1 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs758642782; called by muse, mutect2, varscan2
- GEMIN6 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs772095779; called by muse, mutect2, varscan2
- GIMAP8 | c.826G>C p.G276R | Missense Mutation (SNP) | VAF 123/223 reads (55%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV56233018; called by muse, mutect2, varscan2
- GJA8 | c.881C>G p.A294G | Missense Mutation (SNP) | VAF 211/382 reads (55%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.468); catalogued as COSV99569263, COSV99569526; called by muse, mutect2, varscan2
- GK2 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218862963; called by muse, mutect2, varscan2
- GK2 | c.300G>A p.W100* | Nonsense Mutation (SNP) | VAF 33/91 reads (36%) | catalogued as COSV62627973; called by muse, mutect2, varscan2
- GK5 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67486744; called by muse, mutect2, varscan2
- GLIS2 | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 364/610 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192213553; called by muse, mutect2, varscan2
- GP2 | c.1069C>A p.L357I (on ENST00000381362 / NM_001007240.3; = p.L354I on NM_001502.4) | Missense Mutation (SNP) | VAF 79/106 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56894935; called by muse, mutect2, varscan2
- GPR158 | c.2269C>A p.R757S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66267120; called by muse, mutect2
- GRIN3A | c.1415C>A p.P472H | Missense Mutation (SNP) | VAF 82/114 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100701639; called by muse, mutect2, varscan2
- GRK6 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 161/338 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs753249774; called by muse, mutect2, varscan2
- GRM1 | c.823C>A p.R275S | Missense Mutation (SNP) | VAF 151/357 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.506); catalogued as rs766567009, COSV51198697; called by muse, mutect2, varscan2
- H2AC12 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 119/262 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.038); catalogued as rs778170423, COSV63617316; called by muse, mutect2, varscan2
- H3C4 | c.342C>A p.H114Q | Missense Mutation (SNP) | VAF 194/399 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.623); catalogued as COSV100587268; called by muse, mutect2, varscan2
- HAX1 | c.463del p.Q155Nfs*59 | Frame Shift Del (DEL) | VAF 137/340 reads (40%) | catalogued as COSV55172930; called by mutect2, pindel, varscan2
- HCAR3 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 178/394 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs977516577, COSV63673677; called by muse, mutect2, varscan2
- HCN1 | c.2540C>A p.S847* | Nonsense Mutation (SNP) | VAF 82/177 reads (46%) | catalogued as COSV100300556; called by muse, varscan2
- HCN1 | c.1496del p.G499Efs*32 | Frame Shift Del (DEL) | VAF 109/266 reads (41%) | catalogued as COSV57508108; called by mutect2, pindel, varscan2
- HEATR5B | c.6167C>T p.P2056L | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV51852866; called by muse, mutect2, varscan2
- HERC2 | c.6623C>T p.A2208V | Missense Mutation (SNP) | VAF 118/498 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV55353809; called by muse, mutect2, varscan2
- HERC6 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs777148021; called by muse, mutect2, varscan2
- HIVEP3 | c.4756G>T p.G1586C | Missense Mutation (SNP) | VAF 81/118 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV56020503; called by muse, mutect2
- HMX2 | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 91/283 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs927360192, COSV60592792; called by muse, mutect2, varscan2
- HPSE | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs766025621; called by muse, mutect2, varscan2
- HS3ST4 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.03); catalogued as rs547472104; called by muse, mutect2, varscan2
- HS3ST4 | c.984G>T p.W328C | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100500719, COSV58802705; called by muse, mutect2, varscan2
- HTRA3 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 187/189 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56469510; called by muse, mutect2, varscan2
- HUS1B | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 91/195 reads (47%) | SIFT tolerated (0.74); PolyPhen benign (0.033); catalogued as rs776185878, COSV57867908; called by muse, mutect2, varscan2
- HYDIN | c.6607G>T p.G2203W | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59272155; called by muse, mutect2, varscan2
- IFT88 | c.485G>A p.C162Y (on ENST00000319980 / NM_001318493.2; = p.C153Y on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs779962847; called by muse, mutect2, varscan2
- IGFBP1 | c.455G>T p.W152L | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV51875303; called by muse, mutect2, varscan2
- IGFL3 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 118/205 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as COSV58243312; called by muse, mutect2, varscan2
- IGHV3-13 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 88/162 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); catalogued as rs111986975; called by muse, mutect2, varscan2
- IGLV11-55 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs1568988437; called by muse, mutect2, varscan2
- IGLV2-8 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 298/450 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs757487920; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1750C>A p.L584M | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56254561; called by muse, varscan2
- IL1RAPL1 | c.1781C>G p.A594G | Missense Mutation (SNP) | VAF 96/150 reads (64%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.194); catalogued as COSV100148523; called by muse, varscan2
- IL1RL2 | c.1190A>G p.Q397R | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.856); catalogued as rs1285132837; called by muse, mutect2, varscan2
- INPP4B | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV53734762; called by muse, varscan2
- IPO8 | c.2980G>T p.V994L | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs772601072; called by muse, mutect2, varscan2
- IPO8 | c.2979G>T p.E993D | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.02); catalogued as rs1180971035; called by muse, mutect2, varscan2
- IRS4 | c.3079C>A p.P1027T | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV100929641; called by muse, mutect2, varscan2
- IRX3 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs1189396482; called by muse, mutect2, varscan2
- IRX4 | c.552G>T p.M184I | Missense Mutation (SNP) | VAF 227/757 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99182914; called by muse, mutect2, varscan2
- ITGAD | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303837397; called by muse, mutect2, varscan2
- ITGB8 | c.505G>T p.V169F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV56004933; called by muse, mutect2, varscan2
- KALRN | c.42G>C p.W14C | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious, low confidence (0.04); catalogued as rs1188004725; called by muse, mutect2, varscan2
- KANSL1 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1424923651, COSV99294919; called by muse, mutect2, varscan2
- KCMF1 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101301220; called by muse, mutect2, varscan2
- KCNH3 | c.1040C>G p.P347R | Missense Mutation (SNP) | VAF 387/678 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV57790879; called by muse, mutect2, varscan2
- KCNH6 | c.821C>A p.T274K | Missense Mutation (SNP) | VAF 221/541 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV59002852; called by muse, mutect2, varscan2
- KCNJ4 | c.1315T>A p.Y439N | Missense Mutation (SNP) | VAF 68/108 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV57856463; called by muse, mutect2
- KCNK10 | c.1132C>G p.R378G | Missense Mutation (SNP) | VAF 218/221 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV100067993; called by muse, mutect2, varscan2
- KCNK15 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 98/229 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as rs1445884163; called by muse, mutect2, varscan2
- KHDC4 | c.400G>T p.G134W | Missense Mutation (SNP) | VAF 93/206 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64165998; called by muse, mutect2, varscan2
- KIRREL3 | c.2146C>A p.L716I | Missense Mutation (SNP) | VAF 269/436 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV69385269; called by muse, mutect2, varscan2
- KLHDC7A | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 183/236 reads (78%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.779); catalogued as rs1452627019; called by muse, mutect2, varscan2
- KLHL1 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 27/27 reads (100%) | catalogued as COSV100917321; called by muse, mutect2, varscan2
- KLHL13 | c.1105T>A p.W369R | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53251230; called by muse, mutect2, varscan2
- KLHL15 | c.1677del p.I560Sfs*67 | Frame Shift Del (DEL) | VAF 29/91 reads (32%) | catalogued as COSV60141258; called by mutect2, pindel, varscan2
- KLHL41 | c.1454G>T p.R485L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52929456; called by muse, mutect2, varscan2
- KLK15 | c.481+4C>G | Splice Region (SNP) | VAF 30/69 reads (43%) | catalogued as COSV56827656; called by muse, mutect2, varscan2
- KLK15 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 138/222 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV56826427; called by muse, mutect2, varscan2
- KLRG2 | c.105del p.A36Rfs*91 | Frame Shift Del (DEL) | VAF 128/473 reads (27%) | catalogued as COSV61800408; called by pindel, varscan2
- L3MBTL3 | c.698G>C p.C233S | Missense Mutation (SNP) | VAF 138/271 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs906721951, COSV62386579; called by muse, mutect2, varscan2
- LAMC3 | c.3770G>T p.G1257V | Missense Mutation (SNP) | VAF 320/447 reads (72%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV62655734; called by muse, mutect2, varscan2
- LCE6A | c.165G>T p.R55S | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.26); catalogued as COSV101440604; called by muse, mutect2, varscan2
- LGR5 | c.316C>A p.P106T | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs752965639; called by mutect2, varscan2
- LHX3 | c.928C>A p.R310S (on ENST00000371748 / NM_178138.6; = p.R315S on NM_014564.5) | Missense Mutation (SNP) | VAF 132/168 reads (79%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs548961945; called by muse, mutect2, varscan2
- LHX8 | c.391A>T p.R131W | Missense Mutation (SNP) | VAF 114/148 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99634596; called by muse, mutect2, varscan2
- LILRB1 | c.1393C>A p.P465T (on ENST00000427581; = p.P429T on NM_006669.6) | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs771021905; called by muse, mutect2, varscan2
- LINGO2 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 76/76 reads (100%) | catalogued as COSV58059759; called by muse, mutect2, varscan2
- LIPI | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1207796725; called by muse, mutect2, varscan2
- LMBR1L | c.1168A>T p.T390S | Missense Mutation (SNP) | VAF 86/249 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.412); catalogued as rs1162869875; called by muse, mutect2, varscan2
- LOXHD1 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 77/109 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs748673610; called by muse, mutect2, varscan2
- LPA | c.4337C>T p.P1446L | Missense Mutation (SNP) | VAF 108/256 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100307522; called by muse, mutect2, varscan2
- LRFN2 | c.1846G>T p.A616S | Missense Mutation (SNP) | VAF 114/214 reads (53%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs1345589229, COSV57833079; called by muse, mutect2, varscan2
- LRIT1 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 136/437 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as COSV100928200; called by muse, mutect2, varscan2
- LRIT1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs770262471; called by muse, mutect2, varscan2
- LRP2 | c.4093G>T p.V1365F | Missense Mutation (SNP) | VAF 81/154 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as COSV99786940; called by muse, mutect2, varscan2
- LRRC4C | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 69/91 reads (76%) | SIFT tolerated (0.16); PolyPhen benign (0.257); catalogued as COSV53419153; called by muse, mutect2, varscan2
- LRRC53 | c.902C>A p.A301E | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1183543835; called by muse, mutect2, varscan2
- LRRC7 | c.2107+1del | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | catalogued as COSV50494664; called by mutect2, pindel, varscan2
- LRRK1 | c.1754G>T p.R585L | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV52621830; called by muse, mutect2, varscan2
- LRRN2 | c.1882C>A p.R628S | Missense Mutation (SNP) | VAF 127/332 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.06); catalogued as rs769164284; called by muse, mutect2, varscan2
- LRRTM4 | c.1048G>T p.V350F | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV69139301; called by muse, varscan2
- LTBP1 | c.1210C>A p.H404N (on ENST00000404816 / NM_206943.4; = p.H78N on NM_000627.4) | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV63184526; called by muse, mutect2
- LTBP1 | c.3646G>T p.G1216W (on ENST00000404816 / NM_206943.4; = p.G890W on NM_000627.4) | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV55379956; called by muse, mutect2, varscan2
- LY6L | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 34/99 reads (34%) | catalogued as COSV73805936; called by muse, mutect2, varscan2
- LYST | c.10912G>C p.G3638R | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67714502; called by muse, mutect2, varscan2
- MAB21L1 | c.545G>A p.R182K | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.615); catalogued as rs373870848; called by muse, mutect2, varscan2
- MAGEA10 | c.1055C>G p.T352S | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1320897948; called by mutect2, varscan2
- MAGEB4 | c.55C>A p.R19S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV64397289; called by muse, mutect2, varscan2
- MAGEC1 | c.2065C>A p.L689M | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs762488148; called by muse, mutect2, varscan2
- MAGEL2 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1295086151; called by muse, mutect2, varscan2
- MAP3K19 | c.2048C>A p.T683K | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200164509; called by muse, mutect2, varscan2
- MAP3K5 | c.3986G>T p.R1329L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV62891328; called by muse, mutect2, varscan2
- MDM2 | c.46A>T p.T16S | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV99254558; called by muse, mutect2, varscan2
- MEFV | c.239G>C p.R80P | Missense Mutation (SNP) | VAF 158/453 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV54824451; called by muse, mutect2, varscan2
- MEGF10 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.951); catalogued as COSV57258218; called by muse, mutect2
- MEPCE | c.974G>T p.R325M | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV52768817; called by muse, mutect2, varscan2
- METRNL | c.764G>A p.R255K | Missense Mutation (SNP) | VAF 93/297 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV60761641; called by muse, mutect2, varscan2
- MFSD6 | c.328C>A p.R110S | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752956733; called by muse, mutect2, varscan2
- MGA | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.637); catalogued as rs1246317040, COSV99582033; called by muse, mutect2, varscan2
- MID2 | c.1864G>T p.A622S | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV53308439, COSV53315500; called by muse, mutect2, varscan2
- MIGA1 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.468); catalogued as rs755719015; called by muse, mutect2, varscan2
- MMP16 | c.329G>T p.S110I | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs867643912, COSV54160622; called by muse, mutect2, varscan2
- MMP17 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs759602929, COSV62181642; called by muse, mutect2, varscan2
- MN1 | c.3087C>A p.D1029E | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.077); catalogued as COSV56557674; called by muse, mutect2, varscan2
- MOSPD3 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs775947023, COSV56158849; called by muse, mutect2, varscan2
- MOSPD3 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 220/354 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs778222272; called by muse, mutect2, varscan2
- MRGPRF | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as rs376550077; called by muse, mutect2, varscan2
- MRGPRX3 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV66933255; called by muse, mutect2, varscan2
- MRPS5 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55533073; called by muse, mutect2, varscan2
- MS4A6E | c.220A>T p.N74Y | Missense Mutation (SNP) | VAF 126/261 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as rs1490664728; called by muse, mutect2, varscan2
- MSH3 | c.2656-1G>T p.X886_splice | Splice Site (SNP) | VAF 44/82 reads (54%) | catalogued as COSV99432231; called by muse, varscan2
- MSX1 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 142/144 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV101235698; called by muse, varscan2
- MTUS2 | c.2431A>T p.S811C | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.416); catalogued as COSV70921730; called by muse, mutect2, varscan2
- MTUS2 | c.3307C>T p.R1103W (on ENST00000612955 / NM_001366650.1; = p.R82W on NM_015233.6) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs764707896; called by muse, mutect2, varscan2
- MUC16 | c.30166C>A p.P10056T | Missense Mutation (SNP) | VAF 52/53 reads (98%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.044); catalogued as COSV101202087; called by muse, mutect2, varscan2
- MUC19 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); catalogued as rs1384970154; called by muse, mutect2, varscan2
- MUC4 | c.7255G>C p.V2419L | Missense Mutation (SNP) | VAF 280/1092 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.101); catalogued as rs1220113340; called by muse, mutect2, varscan2
- MXRA5 | c.7195C>A p.Q2399K | Missense Mutation (SNP) | VAF 115/116 reads (99%) | SIFT tolerated (0.75); PolyPhen benign (0.173); catalogued as COSV54239498; called by muse, mutect2, varscan2
- MYH13 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV52820887; called by muse, mutect2, varscan2
- MYH4 | c.2014del p.H672Tfs*26 | Frame Shift Del (DEL) | VAF 42/138 reads (30%) | catalogued as rs1228204503; called by mutect2, pindel, varscan2
- MYH9 | c.3452C>T p.T1151M | Missense Mutation (SNP) | VAF 159/245 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375081687; called by muse, mutect2, varscan2
- MYO15A | c.7402G>C p.E2468Q | Missense Mutation (SNP) | VAF 387/843 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.135); catalogued as rs1412467176, COSV99232507; called by muse, mutect2, varscan2
- MYO7B | c.2524C>A p.L842M | Missense Mutation (SNP) | VAF 230/438 reads (53%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.764); catalogued as COSV67344241; called by muse, mutect2, varscan2
- MYO7B | c.2664del p.E889Rfs*37 | Frame Shift Del (DEL) | VAF 52/119 reads (44%) | catalogued as COSV67348279; called by mutect2, pindel, varscan2
- MYOD1 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 41/121 reads (34%) | catalogued as COSV51452810, COSV51454705; called by muse, mutect2, varscan2
- NAT16 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 138/223 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs369492361; called by muse, mutect2, varscan2
- NAT8 | c.82C>A p.H28N | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV55542950; called by muse, mutect2, varscan2
- NAV3 | c.4345A>G p.T1449A | Missense Mutation (SNP) | VAF 98/192 reads (51%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.993); catalogued as rs1202248307, COSV99031035; called by muse, mutect2, varscan2
- NELL2 | c.1826G>C p.G609A | Missense Mutation (SNP) | VAF 88/154 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.368); catalogued as COSV61569557; called by muse, mutect2, varscan2
- NGEF | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1300856901, COSV50914726, COSV50943982; called by muse, mutect2, varscan2
- NID2 | c.2006T>A p.L669Q | Missense Mutation (SNP) | VAF 143/144 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV53498299; called by muse, mutect2, varscan2
- NLRP1 | c.2737G>T p.D913Y | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.379); catalogued as rs1419431079; called by muse, mutect2, varscan2
- NLRP12 | c.1512C>G p.I504M | Missense Mutation (SNP) | VAF 323/865 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV60755059; called by muse, mutect2, varscan2
- NLRP13 | c.1550A>T p.Y517F | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV100738079; called by muse, mutect2, varscan2
- NLRP2 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 184/336 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV54758420; called by muse, mutect2, varscan2
- NLRP4 | c.2741C>A p.A914E | Missense Mutation (SNP) | VAF 102/159 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs769137352, COSV56707773, COSV56707879; called by muse, mutect2, varscan2
- NOC2L | c.1716G>T p.Q572H | Missense Mutation (SNP) | VAF 159/241 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58988045; called by muse, mutect2, varscan2
- NOP56 | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 90/189 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61388773; called by muse, mutect2, varscan2
- NPAP1 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.412); catalogued as COSV61511600; called by muse, mutect2, varscan2
- NPHS1 | c.191G>A p.W64* | Nonsense Mutation (SNP) | VAF 471/791 reads (60%) | catalogued as CM990949; called by muse, mutect2, varscan2
- NPPC | c.27C>A p.C9* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV54945647; called by muse, mutect2, varscan2
- NR2E1 | c.623C>A p.T208K | Missense Mutation (SNP) | VAF 154/370 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.133); catalogued as COSV64562255; called by muse, mutect2, varscan2
- NR3C2 | c.740G>T p.R247M | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV60985062; called by muse, mutect2, varscan2
- NRG1 | c.1284G>T p.M428I (on ENST00000405005 / NM_013964.5; = p.M433I on NM_013956.5) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55176044; called by muse, mutect2, varscan2
- NRG3 | c.1865T>A p.I622N (on ENST00000404547 / NM_001370084.1; = p.I598N on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as COSV64579875; called by muse, mutect2, varscan2
- NRK | c.3505G>T p.A1169S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs377439740; called by muse, mutect2, varscan2
- NRXN1 | c.4363G>T p.E1455* | Nonsense Mutation (SNP) | VAF 45/145 reads (31%) | catalogued as COSV60520265; called by muse, mutect2, varscan2
- NRXN2 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 299/608 reads (49%) | catalogued as COSV55456916, COSV99634967; called by muse, mutect2, varscan2
- NSUN6 | c.377G>T p.R126I | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66031808; called by muse, mutect2, varscan2
- NUDT6 | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 240/359 reads (67%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs772875454; called by muse, mutect2, varscan2
- OBSL1 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 113/272 reads (42%) | catalogued as COSV54714385, COSV54717312; called by muse, mutect2, varscan2
- OCA2 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 345/712 reads (48%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV62349210; called by muse, mutect2, varscan2
- OGFR | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 84/204 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51697898; called by muse, mutect2, varscan2
- OGT | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs765863058; called by muse, mutect2, varscan2
- OPRM1 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 148/314 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.614); catalogued as rs777099271, COSV100002380; called by muse, mutect2, varscan2
- OPRM1 | c.1117A>G p.R373G | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as rs1355646642; called by muse, mutect2, varscan2
- OR10D3 | c.572A>T p.D191V | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1233714948; called by muse, mutect2, varscan2
- OR10G7 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 72/88 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1565596559, COSV57867392; called by muse, varscan2
- OR10J1 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 130/326 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as rs772118508, COSV71128835; called by muse, mutect2, varscan2
- OR10Q1 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 158/280 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV57470793; called by muse, varscan2
- OR10Q1 | c.437C>A p.T146K | Missense Mutation (SNP) | VAF 113/263 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV57470145; called by muse, varscan2
- OR1D5 | c.479C>A p.T160N | Missense Mutation (SNP) | VAF 156/482 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs577309070; called by muse, mutect2, varscan2
- OR2A1 | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 364/1363 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV101283348; called by muse, mutect2, varscan2
- OR2T12 | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756113026; called by muse, mutect2, varscan2
- OR2T27 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 104/247 reads (42%) | catalogued as COSV100788381; called by muse, mutect2, varscan2
- OR51E2 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756220257, COSV67807507; called by muse, mutect2, varscan2
- OR52D1 | c.425C>G p.A142G | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs780502302, COSV100495159; called by muse, mutect2, varscan2
- OR52E8 | c.252C>G p.I84M | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs755795212; called by muse, mutect2, varscan2
- OR52J3 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 41/58 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs1040215387; called by muse, mutect2, varscan2
- OR5B12 | c.832A>G p.I278V | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV56905083; called by muse, mutect2, varscan2
- OR5B12 | c.503G>T p.R168I | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.144); catalogued as COSV100222579, COSV56904724; called by muse, mutect2, varscan2
- OR5D13 | c.584A>T p.Y195F | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV62333067, COSV62333880; called by muse, mutect2, varscan2
- OR5H2 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV62351041; called by muse, mutect2, varscan2
- OR5K4 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100721331; called by muse, mutect2, varscan2
- OR5R1 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56571664; called by muse, mutect2, varscan2
- OR6B3 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as rs1250544037, COSV100097298; called by muse, mutect2, varscan2
- OR8H2 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57943721; called by muse, varscan2
- OR9Q2 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 98/197 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV61112009; called by muse, mutect2, varscan2
- OTOF | c.1480C>A p.R494S | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55512507, COSV55516456; called by muse, mutect2, varscan2
- OTOG | c.4132G>A p.A1378T | Missense Mutation (SNP) | VAF 136/190 reads (72%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs976267798; called by muse, mutect2, varscan2
- OVCH1 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV58961568; called by muse, mutect2, varscan2
- OXER1 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 130/409 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV54310621; called by muse, mutect2, varscan2
- P4HB | c.1275G>A p.M425I | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.688); catalogued as rs149469078; called by muse, mutect2, varscan2
- PADI6 | c.1408del p.E470Sfs*7 | Frame Shift Del (DEL) | VAF 106/202 reads (52%) | catalogued as COSV100640014; called by mutect2, pindel, varscan2
- PASD1 | c.1633G>T p.E545* | Nonsense Mutation (SNP) | VAF 71/175 reads (41%) | catalogued as COSV64857672; called by muse, mutect2
- PCDHA10 | c.2351G>C p.G784A | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV100252645; called by muse, mutect2, varscan2
- PCDHA11 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 136/430 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV56505342; called by muse, mutect2, varscan2
- PCDHA3 | c.1192G>T p.V398L | Missense Mutation (SNP) | VAF 92/329 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.213); catalogued as COSV63542430; called by muse, mutect2, varscan2
- PCDHA3 | c.1449C>A p.D483E | Missense Mutation (SNP) | VAF 212/677 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1230044523, COSV63542712; called by muse, mutect2, varscan2
- PCDHA8 | c.2066C>A p.P689Q | Missense Mutation (SNP) | VAF 120/343 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.018); catalogued as rs782229636, COSV65323709; called by muse, mutect2, varscan2
- PCDHB2 | c.1814C>A p.S605* | Nonsense Mutation (SNP) | VAF 250/507 reads (49%) | catalogued as COSV99164107; called by muse, mutect2, varscan2
- PCDHB3 | c.1225C>A p.L409M | Missense Mutation (SNP) | VAF 81/118 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs202034696; called by muse, mutect2, varscan2
- PCDHB4 | c.2217C>A p.S739R | Missense Mutation (SNP) | VAF 88/319 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.272); catalogued as COSV52020200; called by muse, mutect2, varscan2
- PCDHB6 | c.2186C>G p.P729R | Missense Mutation (SNP) | VAF 129/204 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50699349; called by muse, mutect2, varscan2
- PCDHGA11 | c.1909G>T p.D637Y | Missense Mutation (SNP) | VAF 146/230 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53915470, COSV53917862; called by muse, mutect2, varscan2
- PCDHGA4 | c.2205C>A p.F735L | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53952655; called by muse, mutect2, varscan2
- PCDHGB3 | c.1002G>T p.Q334H | Missense Mutation (SNP) | VAF 59/96 reads (61%) | SIFT tolerated (0.56); PolyPhen benign (0.055); catalogued as COSV54003448, COSV99538013; called by muse, mutect2, varscan2
- PCIF1 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100976006; called by muse, mutect2, varscan2
- PDE6C | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV65114990; called by muse, mutect2, varscan2
- PDGFRB | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as rs759684681, COSV99940794; called by muse, varscan2
- PDLIM3 | c.118C>T p.H40Y (on ENST00000284770 / NM_001257963.1; = p.H119Y on NM_014476.6) | Missense Mutation (SNP) | VAF 174/263 reads (66%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.975); catalogued as COSV52978642; called by muse, mutect2, varscan2
- PDZRN3 | c.1453G>C p.V485L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs747518866; called by muse, mutect2, varscan2
- PEG3 | c.3793C>A p.P1265T | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs909324686, COSV55645327, COSV55646290; called by muse, mutect2, varscan2
- PEX10 | c.394G>T p.G132W | Missense Mutation (SNP) | VAF 83/301 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV56580867; called by muse, mutect2, varscan2
- PGAM2 | c.184C>G p.R62G | Missense Mutation (SNP) | VAF 336/934 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs922606034; called by muse, mutect2, varscan2
- PGC | c.1036G>T p.G346* | Nonsense Mutation (SNP) | VAF 67/131 reads (51%) | catalogued as COSV57823628; called by muse, mutect2, varscan2
- PHACTR3 | c.692C>A p.P231H | Missense Mutation (SNP) | VAF 185/348 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV63028207; called by muse, mutect2, varscan2
- PHKB | c.1835A>G p.H612R | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1189750988; called by muse, mutect2, varscan2
- PI16 | c.149C>A p.T50K | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV65448281; called by muse, mutect2, varscan2
- PIEZO2 | c.5703C>G p.Y1901* | Nonsense Mutation (SNP) | VAF 80/128 reads (63%) | catalogued as COSV99555045; called by muse, mutect2, varscan2
- PIK3CG | c.971C>A p.P324Q | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV63250351; called by muse, mutect2, varscan2
- PJA1 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 46/47 reads (98%) | catalogued as COSV100824740; called by muse, mutect2, varscan2
- PKHD1L1 | c.3796G>T p.G1266* | Nonsense Mutation (SNP) | VAF 34/51 reads (67%) | catalogued as COSV101006192; called by muse, mutect2, varscan2
- PKP1 | c.1850C>A p.S617Y | Missense Mutation (SNP) | VAF 252/358 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV55822269; called by muse, mutect2, varscan2
- PKP2 | c.1688+1G>T p.X563_splice | Splice Site (SNP) | VAF 35/55 reads (64%) | catalogued as CS102835; called by mutect2, varscan2
- PLA2G4A | c.602C>A p.A201D | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771536222; called by mutect2, varscan2
- PLBD2 | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 163/426 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745951952, COSV55107187; called by muse, mutect2, varscan2
- PLCE1 | c.4022G>T p.C1341F | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.048); catalogued as rs759458474; called by muse, mutect2, varscan2
- PLCL1 | c.1972G>T p.D658Y | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV70820641; called by muse, mutect2, varscan2
- PLCZ1 | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 76/109 reads (70%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as rs1473420795; called by muse, mutect2, varscan2
- PLEC | c.4587G>T p.E1529D (on ENST00000322810 / NM_201380.4; = p.E1419D on NM_000445.5) | Missense Mutation (SNP) | VAF 113/366 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV59600111; called by muse, mutect2, varscan2
- PLG | c.1618G>T p.G540C | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51981910; called by muse, mutect2, varscan2
- PLK5 | c.567G>T p.P189= | Splice Region (SNP) | VAF 164/164 reads (100%) | catalogued as rs773689990; called by muse, mutect2, varscan2
- PNPLA7 | c.2651C>G p.P884R | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53007399; called by muse, mutect2, varscan2
- POF1B | c.1159C>A p.Q387K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs1027909143; called by muse, mutect2, varscan2
- POLL | c.824G>T p.R275M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100150074; called by muse, mutect2, varscan2
- POLR2G | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.496); catalogued as COSV57135026; called by muse, mutect2, varscan2
- POTEC | c.225C>A p.S75R | Missense Mutation (SNP) | VAF 275/477 reads (58%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV62800472, COSV62805903; called by muse, mutect2, varscan2
- POTEI | c.2404C>A p.P802T | Missense Mutation (SNP) | VAF 294/554 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs200337322; called by mutect2, varscan2
- POTEJ | c.2780C>A p.P927H | Missense Mutation (SNP) | VAF 349/878 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV68639955; called by muse, varscan2
- PPFIA2 | c.2090G>T p.R697M | Missense Mutation (SNP) | VAF 116/241 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1247295933; called by muse, mutect2, varscan2
- PPFIA4 | c.1975G>T p.D659Y (on ENST00000447715; = p.D660Y on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.27); catalogued as COSV99690301; called by muse, mutect2, varscan2
- PRDM9 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 205/457 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV57013427; called by muse, mutect2, varscan2
- PREX1 | c.848C>A p.A283E | Missense Mutation (SNP) | VAF 133/269 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64247740; called by muse, mutect2, varscan2
- PRG4 | c.2492C>A p.P831H | Missense Mutation (SNP) | VAF 183/304 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV63356528; called by muse, mutect2, varscan2
- PRICKLE3 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.735); catalogued as rs782158023; called by muse, mutect2, varscan2
- PRODH2 | c.566C>A p.T189N (on ENST00000301175; = p.T113N on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/227 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as COSV99040616; called by muse, mutect2, varscan2
- PRPF38A | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.775); catalogued as COSV99933516; called by muse, mutect2, varscan2
- PRX | c.4118G>A p.R1373Q | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as rs763294661, COSV52523514; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSMC6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 103/103 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV101471196; called by muse, mutect2, varscan2
- PSME4 | c.4154G>C p.G1385A | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66364880; called by muse, mutect2, varscan2
- PTCH2 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 108/151 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV64709527; called by muse, mutect2, varscan2
- PTPRD | c.4013C>A p.P1338H | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV61962282; called by muse, mutect2, varscan2
- PTPRD | c.3502G>T p.E1168* | Nonsense Mutation (SNP) | VAF 68/69 reads (99%) | catalogued as COSV61937662; called by muse, mutect2, varscan2
- PTPRQ | c.3768A>T p.L1256F (on ENST00000616559; = p.L1214F on NM_001145026.2) | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0.181); catalogued as rs1291688801; called by muse, mutect2, varscan2
- PXDNL | c.3659T>A p.V1220D | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100684969; called by muse, mutect2, varscan2
- PXDNL | c.3080C>G p.T1027S | Missense Mutation (SNP) | VAF 120/227 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100684128; called by muse, mutect2, varscan2
- PXDNL | c.2829G>T p.E943D | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs147566293; called by muse, mutect2, varscan2
- RAB39B | c.557G>T p.W186L | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as CM108101; called by muse, mutect2, varscan2
- RANBP2 | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 98/199 reads (49%) | catalogued as COSV51695545; called by muse, mutect2, varscan2
- RASAL2 | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 99/293 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs199550328; called by muse, mutect2, varscan2
- RBAK | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV62331242; called by muse, mutect2, varscan2
- REEP3 | c.106-1G>T p.X36_splice | Splice Site (SNP) | VAF 28/57 reads (49%) | catalogued as rs368074557; called by muse, mutect2, varscan2
- REG3A | c.119G>T p.C40F | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59410912; called by muse, mutect2, varscan2
- RELN | c.1803G>C p.W601C | Missense Mutation (SNP) | VAF 117/194 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100634258; called by muse, mutect2, varscan2
- RFFL | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 99/199 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52074250; called by muse, mutect2, varscan2
- RGS7 | c.449C>G p.A150G | Missense Mutation (SNP) | VAF 76/241 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV58557718; called by muse, mutect2, varscan2
- RNF2 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100835621; called by muse, mutect2, varscan2
- RNF31 | c.2875G>T p.A959S | Missense Mutation (SNP) | VAF 111/192 reads (58%) | SIFT tolerated (0.54); PolyPhen benign (0.146); catalogued as COSV100138254; called by muse, mutect2, varscan2
- ROBO1 | c.3046A>T p.I1016L | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (0.39); PolyPhen benign (0.358); catalogued as COSV71392655, COSV71397188; called by muse, mutect2, varscan2
- ROBO2 | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 207/312 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765218623, COSV59936575; called by muse, mutect2, varscan2
- ROS1 | c.3528G>T p.W1176C | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63855251; called by muse, mutect2, varscan2
- RP1L1 | c.5065C>A p.L1689M | Missense Mutation (SNP) | VAF 51/69 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763468681; called by muse, mutect2, varscan2
- RP1L1 | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 154/411 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.234); catalogued as rs967433739; called by muse, mutect2, varscan2
- RPGR | c.92G>T p.W31L | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as CM1410801; called by muse, mutect2, varscan2
- RPH3A | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0.026); catalogued as COSV101231886; called by muse, mutect2, varscan2
- RPL15 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 129/138 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1466906873; called by muse, mutect2, varscan2
- RPTOR | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV60814499; called by muse, mutect2, varscan2
- RRP8 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs766876049; called by muse, mutect2, varscan2
- RSAD2 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV101150028; called by muse, mutect2, varscan2
- RUNX1T1 | c.1072G>T p.D358Y (on ENST00000265814 / NM_001198628.1; = p.D331Y on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/97 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56158111, COSV56162539; called by muse, mutect2, varscan2
- RXFP3 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 98/230 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV57504628; called by muse, varscan2
- RXFP3 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 184/378 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV57503944, COSV57504531; called by muse, varscan2
- RYR2 | c.12579C>G p.C4193W | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as CM156360, COSV63676152; called by muse, mutect2, varscan2
- RYR3 | c.3418C>A p.R1140S | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs748509983, COSV66801387; called by muse, mutect2, varscan2
- RYR3 | c.12377C>A p.A4126E (on ENST00000389232; = p.A4127E on NM_001036.6) | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66786898; called by muse, mutect2, varscan2
- SAGE1 | c.2363C>A p.T788N | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.381); catalogued as COSV61016976; called by muse, mutect2, varscan2
- SAMD4B | c.50G>C p.W17S | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58753338; called by muse, mutect2, varscan2
- SBK2 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 107/174 reads (61%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs542381455, COSV60014998; called by muse, mutect2, varscan2
- SBNO1 | c.2569G>A p.D857N (on ENST00000420886; = p.D856N on NM_018183.5) | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV57345776; called by muse, mutect2, varscan2
- SCN5A | c.3432G>T p.M1144I (on ENST00000333535 / NM_198056.3; = p.M1143I on NM_000335.5) | Missense Mutation (SNP) | VAF 118/118 reads (100%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV61118294; called by muse, mutect2, varscan2
- SCRT2 | c.914C>A p.P305Q | Missense Mutation (SNP) | VAF 77/158 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as COSV55729340; called by muse, mutect2, varscan2
- SCYL3 | c.1582G>A p.E528K (on ENST00000367770; = p.E474K on NM_020423.7) | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs1558114484; called by muse, mutect2, varscan2
- SEC31A | c.1700G>T p.G567V (on ENST00000355196 / NM_001318120.1; = p.G528V on NM_016211.4) | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV52344473; called by muse, mutect2, varscan2
- SEMA5A | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 81/134 reads (60%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs202090123; called by muse, mutect2, varscan2
- SEPTIN8 | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99736539; called by muse, mutect2, varscan2
- SERPIND1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs750892575; called by muse, mutect2, varscan2
- SEZ6L | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 93/307 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.417); catalogued as rs1335794595; called by muse, mutect2, varscan2
- SGCA | c.100C>A p.R34S | Missense Mutation (SNP) | VAF 181/505 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.327); catalogued as CM971332, COSV100006938; called by muse, mutect2, varscan2
- SGCA | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 182/505 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.696); catalogued as CM163140, CM951149, COSV56249347; called by muse, mutect2, varscan2
- SGCG | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755404457, COSV54565762; called by muse, mutect2, varscan2
- SH3PXD2B | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 201/398 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1354278433; called by muse, mutect2, varscan2
- SHC4 | c.384C>A p.S128R | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); catalogued as rs200771635, COSV60109691, COSV60110940; called by muse, mutect2, varscan2
- SLC10A4 | c.396C>A p.H132Q | Missense Mutation (SNP) | VAF 114/114 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.331); catalogued as rs1465798668; called by muse, mutect2, varscan2
- SLC12A3 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99344907; called by muse, mutect2, varscan2
- SLC14A1 | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs768136769; called by muse, mutect2, varscan2
- SLC17A4 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV64957478; called by muse, mutect2, varscan2
- SLC18A2 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 120/199 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750968281; called by muse, mutect2, varscan2
- SLC22A1 | c.1577A>T p.K526M | Missense Mutation (SNP) | VAF 93/190 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs748571557; called by muse, mutect2, varscan2
- SLC24A2 | c.747G>T p.L249F | Missense Mutation (SNP) | VAF 153/154 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53856378; called by muse, mutect2, varscan2
- SLC25A43 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776691094, COSV54219306; called by muse, mutect2, varscan2
- SLC30A10 | c.773C>A p.T258K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV63070770; called by muse, mutect2, varscan2
- SLC32A1 | c.743C>A p.T248K | Missense Mutation (SNP) | VAF 171/342 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.918); catalogued as COSV54146196; called by mutect2, varscan2
- SLC6A16 | c.1555G>A p.G519S | Missense Mutation (SNP) | VAF 208/387 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs1321475223; called by muse, varscan2
- SLC6A4 | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 85/173 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.112); catalogued as COSV104377579; called by muse, mutect2, varscan2
- SLC7A13 | c.417G>T p.L139F | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52536234; called by muse, mutect2, varscan2
- SLC7A3 | c.1282C>T p.L428F | Missense Mutation (SNP) | VAF 47/47 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99979582; called by muse, mutect2, varscan2
- SLC9B1 | c.1354C>A p.L452I | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99599059; called by muse, mutect2, varscan2
- SLIT3 | c.82G>T p.G28W | Missense Mutation (SNP) | VAF 125/224 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs924415374; called by muse, varscan2
- SMARCA4 | c.3582del p.Q1195Sfs*21 | Frame Shift Del (DEL) | VAF 424/588 reads (72%) | catalogued as COSV60789775, COSV60800634; called by mutect2, pindel, varscan2
- SMARCAL1 | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 166/407 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV61919905; called by muse, mutect2, varscan2
- SNX32 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 167/355 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV57449456; called by muse, mutect2, varscan2
- SOBP | c.2504C>A p.A835E | Missense Mutation (SNP) | VAF 223/462 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV57996980; called by muse, varscan2
- SORBS3 | c.1697G>T p.R566L | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV99531277; called by muse, mutect2, varscan2
- SORCS1 | c.2390C>A p.P797Q | Missense Mutation (SNP) | VAF 75/124 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53853541; called by muse, mutect2, varscan2
- SORCS2 | c.1562A>T p.D521V | Missense Mutation (SNP) | VAF 140/140 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1191729971; called by muse, mutect2, varscan2
- SORCS3 | c.2257G>C p.E753Q | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.932); catalogued as COSV63794514; called by muse, mutect2, varscan2
- SOS1 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 45/155 reads (29%) | catalogued as COSV67673938; called by muse, mutect2, varscan2
- SOX7 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs757143423; called by muse, mutect2
- SPEG | c.3232G>T p.G1078C | Missense Mutation (SNP) | VAF 164/353 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56669497; called by muse, mutect2, varscan2
- SPTA1 | c.4069G>T p.D1357Y | Missense Mutation (SNP) | VAF 126/236 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV63751723; called by muse, mutect2, varscan2
- SPTA1 | c.3069G>C p.Q1023H | Missense Mutation (SNP) | VAF 195/415 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63751424; called by muse, mutect2, varscan2
- SPTA1 | c.1300C>G p.Q434E | Missense Mutation (SNP) | VAF 181/373 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV63761147; called by muse, mutect2, varscan2
- SPTB | c.2998C>A p.L1000M | Missense Mutation (SNP) | VAF 226/227 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as COSV67634745; called by muse, mutect2, varscan2
- SPTBN4 | c.6230G>A p.G2077D | Missense Mutation (SNP) | VAF 158/265 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100152301; called by muse, mutect2, varscan2
- SRFBP1 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1464559952; called by muse, mutect2, varscan2
- SSPN | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 92/129 reads (71%) | catalogued as COSV99658574; called by muse, mutect2, varscan2
- ST7 | c.818G>C p.R273P (on ENST00000265437 / NM_021908.3; = p.R250P on NM_018412.4) | Missense Mutation (SNP) | VAF 82/220 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV55392036; called by muse, mutect2, varscan2
- STAB2 | c.2742C>A p.C914* | Nonsense Mutation (SNP) | VAF 140/318 reads (44%) | catalogued as COSV66346198, COSV66346787; called by muse, mutect2, varscan2
- STAM2 | c.1180-1G>A p.X394_splice | Splice Site (SNP) | VAF 43/85 reads (51%) | catalogued as rs1410970149, COSV55730205; called by muse, mutect2, varscan2
- STRIP1 | c.669G>T p.M223I | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV63929780; called by muse, mutect2, varscan2
- SV2B | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 169/346 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57700728; called by muse, mutect2, varscan2
- SYN1 | c.1930G>T p.V644L | Missense Mutation (SNP) | VAF 97/204 reads (48%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1450465858; called by muse, mutect2, varscan2
- SYNDIG1L | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 230/231 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779184482, COSV100526632; called by muse, mutect2, varscan2
- SYNGAP1 | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 257/511 reads (50%) | catalogued as rs1554121276; called by muse, mutect2, varscan2
- SYNGR1 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 252/409 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766039979, COSV53369106; called by muse, mutect2, varscan2
- SYNPO2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100205375; called by muse, mutect2, varscan2
- SYNPO2 | c.838G>T p.G280* | Nonsense Mutation (SNP) | VAF 55/93 reads (59%) | catalogued as COSV61109626; called by muse, mutect2, varscan2
- SYT13 | c.662G>T p.W221L | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50073552; called by muse, mutect2, varscan2
- SYT14 | c.1349C>A p.P450Q | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99656470; called by muse, mutect2, varscan2
- SYTL2 | c.473G>T p.R158M | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60355831; called by muse, mutect2, varscan2
- TAFA1 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 69/110 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs758404527; called by muse, mutect2, varscan2
- TBX15 | c.1580G>C p.R527T (on ENST00000369429 / NM_001330677.2; = p.R421T on NM_152380.3) | Missense Mutation (SNP) | VAF 103/417 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV99254947; called by muse, mutect2, varscan2
- TBX5 | c.612C>A p.H204Q | Missense Mutation (SNP) | VAF 188/355 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100091084; called by muse, mutect2, varscan2
- TCAF1 | c.2539C>T p.R847C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs1332908680; called by mutect2, varscan2
- TCAF2 | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 119/618 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV62050747; called by muse, mutect2, varscan2
- TCF21 | c.359C>A p.T120K | Missense Mutation (SNP) | VAF 173/327 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52819117; called by muse, mutect2, varscan2
- TENM2 | c.439C>A p.R147S | Missense Mutation (SNP) | VAF 146/317 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.573); catalogued as rs752353786, COSV72852991; called by muse, mutect2, varscan2
- TENM2 | c.3077G>T p.R1026L (on ENST00000518659 / NM_001122679.2; = p.R794L on NM_001080428.3) | Missense Mutation (SNP) | VAF 79/186 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV101318020, COSV69134319; called by muse, mutect2, varscan2
- TENM3 | c.8054C>A p.A2685D | Missense Mutation (SNP) | VAF 151/244 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV69301437; called by muse, mutect2, varscan2
- TENM4 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.133); catalogued as rs546728680, COSV53620242; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEP1 | c.4289A>T p.Q1430L | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV53000658; called by muse, mutect2, varscan2
- TERB2 | c.317G>C p.W106S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61650545; called by muse, mutect2, varscan2
- TET1 | c.1703T>C p.M568T | Missense Mutation (SNP) | VAF 67/93 reads (72%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs770830999; called by muse, mutect2, varscan2
- TEX35 | c.460T>C p.C154R | Missense Mutation (SNP) | VAF 270/455 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV99275019; called by muse, mutect2, varscan2
- TEX37 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.006); catalogued as rs375537087, COSV57556032, COSV57557050; called by muse, mutect2, varscan2
- TFEC | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1205356944; called by muse, mutect2, varscan2
- THAP1 | c.570A>T p.K190N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as CD120401; called by muse, mutect2, varscan2
- THOC2 | c.4442G>C p.R1481P | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55543980, COSV99834326; called by muse, mutect2, varscan2
- THSD7B | c.4076G>C p.S1359T (on ENST00000272643; = p.S1357T on NM_001316349.2) | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs865831832; called by muse, mutect2, varscan2
- TIE1 | c.2424C>G p.I808M | Missense Mutation (SNP) | VAF 137/580 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV65249186; called by muse, mutect2, varscan2
- TLDC2 | c.450G>C p.W150C | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1482832087; called by muse, mutect2, varscan2
- TLL1 | c.1673C>A p.S558Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50315534; called by muse, mutect2, varscan2
- TLR4 | c.1934C>A p.S645Y (on ENST00000355622 / NM_138554.5; = p.S605Y on NM_003266.4) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.284); catalogued as rs560472197, COSV100842621; called by muse, mutect2, varscan2
- TLR9 | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 84/84 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62348206; called by muse, mutect2, varscan2
- TMEM132D | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 260/502 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.09); catalogued as rs773867246, COSV70596126, COSV70610579; called by muse, mutect2, varscan2
- TMEM132E | c.1423G>T p.V475F (on ENST00000321639; = p.V565F on NM_001304438.2) | Missense Mutation (SNP) | VAF 73/156 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV58696991; called by muse, mutect2, varscan2
- TNXB | c.8854G>T p.V2952L (on ENST00000647633; = p.V2705L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/305 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV64486308; called by muse, mutect2, varscan2
- TP53 | c.421_423del p.C141del | In Frame Del (DEL) | VAF 107/242 reads (44%) | catalogued as COSV53637140; called by mutect2, pindel, varscan2
- TPH1 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761126088; called by muse, mutect2, varscan2
- TRIM16L | c.126G>C p.R42S | Missense Mutation (SNP) | VAF 222/504 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV101192583; called by muse, mutect2, varscan2
- TRIM77 | c.356C>A p.P119Q | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.836); catalogued as rs1253783454, COSV101242270; called by muse, mutect2
- TRPC1 | c.1014G>T p.Q338H (on ENST00000476941 / NM_001251845.2; = p.Q304H on NM_003304.4) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV56428213; called by muse, mutect2, varscan2
- TRPM5 | c.2689C>A p.P897T | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV50194808; called by muse, mutect2, varscan2
- TRPM6 | c.3330C>A p.H1110Q | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs368851886; called by muse, mutect2, varscan2
- TRPV6 | c.655G>C p.V219L | Missense Mutation (SNP) | VAF 163/272 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV63890904; called by muse, mutect2, varscan2
- TSHZ3 | c.1558del p.D521Ifs*10 | Frame Shift Del (DEL) | VAF 95/185 reads (51%) | catalogued as COSV99551832; called by mutect2, varscan2
- TSPYL6 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 155/508 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as COSV57813174; called by muse, varscan2
- TTC26 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58274524; called by muse, mutect2, varscan2
- TXNDC15 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs139383071; called by muse, mutect2, varscan2
- TYR | c.878C>G p.P293R | Missense Mutation (SNP) | VAF 112/189 reads (59%) | SIFT tolerated (0.38); PolyPhen benign (0.09); catalogued as COSV54475220; called by muse, mutect2, varscan2
- UCP1 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs769316561, COSV99530059; called by muse, mutect2, varscan2
- UFL1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs760861177; called by muse, mutect2, varscan2
- UGT2A2 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1358635261; called by muse, mutect2, varscan2
- UNC13C | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as rs1473661188; called by muse, mutect2, varscan2
- UNC80 | c.4179G>T p.K1393N | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55887262, COSV55913150; called by muse, varscan2
- UNC80 | c.4342G>T p.G1448C | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs943426482, COSV99781344; called by muse, mutect2, varscan2
- UNCX | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 99/224 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as rs1312705326; called by muse, mutect2, varscan2
- USP17L4 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.166); catalogued as rs1459352809; called by mutect2, varscan2
- USP32 | c.4739G>T p.G1580V | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56267129; called by muse, mutect2, varscan2
- UTRN | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as COSV62335031; called by muse, mutect2, varscan2
- VCAN | c.6599C>T p.T2200I | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV54102029; called by muse, mutect2, varscan2
- VMP1 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV51873185; called by muse, mutect2, varscan2
- VPS33A | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV57358359; called by muse, mutect2, varscan2
- VSIG4 | c.178C>A p.R60S | Missense Mutation (SNP) | VAF 79/79 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs751653148; called by muse, mutect2, varscan2
- VWDE | c.2075T>A p.L692Q | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.727); catalogued as COSV51725838; called by muse, mutect2, varscan2
- VWF | c.6893C>A p.T2298K | Missense Mutation (SNP) | VAF 147/480 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as COSV99780180; called by muse, mutect2, varscan2
- VWF | c.5456-1G>T p.X1819_splice | Splice Site (SNP) | VAF 181/275 reads (66%) | catalogued as COSV99777831; called by muse, mutect2, varscan2
- VWF | c.2927G>T p.R976L | Missense Mutation (SNP) | VAF 85/404 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV54610591; called by muse, mutect2, varscan2
- WDR81 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 141/304 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs200343855; called by muse, mutect2, varscan2
- WNT1 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 154/397 reads (39%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.035); catalogued as COSV99525296; called by muse, mutect2, varscan2
- WNT11 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 482/865 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs376706959; called by muse, mutect2, varscan2
- WT1 | c.1502C>A p.A501E | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs749266841, COSV60086824, COSV60087202; called by muse, mutect2, varscan2
- XIRP2 | c.3949T>C p.W1317R (on ENST00000628543; = p.W1492R on NM_152381.6) | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54704954; called by muse, mutect2, varscan2
- XPO1 | c.1798G>T p.V600F | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68946129; called by muse, mutect2, varscan2
- XYLT1 | c.1909G>T p.E637* | Nonsense Mutation (SNP) | VAF 92/313 reads (29%) | catalogued as COSV54485648; called by muse, mutect2, varscan2
- YEATS2 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV59363392; called by muse, mutect2, varscan2
- ZADH2 | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 61/104 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1445520579; called by muse, mutect2, varscan2
- ZC3H11A | c.703G>T p.G235C | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV59750698; called by muse, mutect2, varscan2
- ZC3H6 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as COSV59669674; called by muse, mutect2, varscan2
- ZDHHC11 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 63/374 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52062012; called by muse, mutect2, varscan2
- ZEB2 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV100356712; called by muse, mutect2, varscan2
- ZFHX4 | c.4703A>T p.K1568M | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50532233; called by muse, mutect2, varscan2
- ZFHX4 | c.8491G>A p.G2831R | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs554869311, COSV50704827, COSV99268698; called by muse, mutect2, varscan2
- ZFP1 | c.16-2A>T p.X6_splice | Splice Site (SNP) | VAF 35/106 reads (33%) | catalogued as COSV60033672; called by muse, mutect2, varscan2
- ZFPM2 | c.2481C>G p.D827E | Missense Mutation (SNP) | VAF 139/203 reads (68%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV65872371; called by muse, mutect2, varscan2
- ZIC3 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 175/356 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54975768; called by muse, mutect2, varscan2
- ZIM3 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT tolerated (0.54); PolyPhen benign (0.232); catalogued as rs1209117682, COSV99518008; called by muse, mutect2, varscan2
- ZMAT1 | c.1819G>T p.E607* | Nonsense Mutation (SNP) | VAF 45/91 reads (49%) | catalogued as COSV100858822; called by muse, varscan2
- ZMAT1 | c.1805A>G p.H602R | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT tolerated (0.6); PolyPhen benign (0.059); catalogued as rs372063692, COSV65657672; called by muse, varscan2
- ZNF284 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.588); catalogued as rs377613949; called by muse, mutect2, varscan2
- ZNF285 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 117/177 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1462307043; called by muse, mutect2, varscan2
- ZNF33A | c.2033G>T p.G678V (on ENST00000458705 / NM_006974.3; = p.G679V on NM_006954.2) | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.23); catalogued as rs766382393, COSV100275834; called by muse, mutect2, varscan2
- ZNF467 | c.1634G>T p.C545F | Missense Mutation (SNP) | VAF 70/120 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57374220; called by muse, mutect2, varscan2
- ZNF479 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 73/132 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100482716; called by muse, mutect2, varscan2
- ZNF521 | c.1547C>A p.P516H | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as COSV64124861; called by muse, mutect2, varscan2
- ZNF571 | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs768648883; called by muse, mutect2, varscan2
- ZNF585A | c.1119G>T p.Q373H (on ENST00000292841 / NM_001288800.2; = p.Q318H on NM_152655.3) | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV53066999; called by muse, mutect2, varscan2
- ZNF628 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 140/363 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs926712381; called by muse, mutect2, varscan2
- ZNF711 | c.133G>T p.V45F | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV52153663; called by muse, mutect2, varscan2
- ZNF726 | c.1958G>C p.C653S | Missense Mutation (SNP) | VAF 62/63 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs543650451; called by muse, mutect2, varscan2
- ZNF727 | c.1252C>A p.H418N | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs761366126, COSV101407008, COSV101407018; called by muse, mutect2, varscan2
- ZNF765 | c.1412G>T p.C471F | Missense Mutation (SNP) | VAF 88/168 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs762554302; called by muse, mutect2
- ZNF804A | c.2864C>T p.P955L | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV56443184; called by muse, mutect2, varscan2
- ZNF831 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs760029924, COSV64038403; called by muse, mutect2, varscan2
- ZNF845 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101508952; called by muse, mutect2, varscan2
- ZNRF4 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 220/221 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV55774484; called by muse, mutect2, varscan2
- ZZZ3 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs1324918070; called by muse, mutect2, varscan2
- A2M | c.3655G>T p.A1219S | Missense Mutation (SNP) | VAF 219/317 reads (69%) | SIFT tolerated (0.22); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ABCA6 | c.1769A>T p.E590V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- ABCA9 | c.3223G>C p.V1075L | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ABCA9 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCB5 | c.53+2T>A p.X18_splice | Splice Site (SNP) | VAF 29/99 reads (29%) | called by muse, mutect2, varscan2
- ABCC12 | c.3254C>A p.T1085N | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ABCC12 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 49/78 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ABCC2 | c.1531-1G>T p.X511_splice | Splice Site (SNP) | VAF 38/136 reads (28%) | called by muse, mutect2, varscan2
- ABCC9 | c.3214C>A p.L1072I | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ABCC9 | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ABCC9 | c.1330G>T p.G444C | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ABCC9 | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- ABCG5 | c.319G>T p.G107W | Missense Mutation (SNP) | VAF 224/616 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABR | c.890G>T p.G297V (on ENST00000302538 / NM_021962.5; = p.G260V on NM_001092.5) | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, varscan2
- ACCS | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ACTA1 | c.1073G>C p.W358S | Missense Mutation (SNP) | VAF 249/375 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTRT1 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ADA | c.436del p.V146Sfs*33 | Frame Shift Del (DEL) | VAF 233/574 reads (41%) | called by mutect2, pindel, varscan2
- ADA | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 153/320 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAD1 | c.1041A>G p.I347M | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (0.17); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ADAM10 | c.1906A>T p.R636* | Nonsense Mutation (SNP) | VAF 119/233 reads (51%) | called by muse, mutect2, varscan2
- ADAM19 | c.2364G>T p.Q788H | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- ADAM2 | c.1226T>C p.I409T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ADAM22 | c.445G>T p.V149F | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADAM22 | c.489C>A p.D163E | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS13 | c.2314G>T p.A772S | Missense Mutation (SNP) | VAF 232/328 reads (71%) | SIFT tolerated (0.3); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ADAMTS17 | c.3159G>T p.Q1053H | Missense Mutation (SNP) | VAF 215/446 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS17 | c.3028G>T p.E1010* | Nonsense Mutation (SNP) | VAF 90/181 reads (50%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.1583C>A p.P528Q | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ADAMTS20 | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ADAMTS4 | c.900C>A p.N300K | Missense Mutation (SNP) | VAF 142/328 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ADCY2 | c.663G>T p.Q221H | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ADCY8 | c.2054G>T p.R685I | Missense Mutation (SNP) | VAF 128/194 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, varscan2
- ADCY9 | c.117del p.N40Tfs*59 | Frame Shift Del (DEL) | VAF 38/176 reads (22%) | called by mutect2, pindel, varscan2
- ADD3 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ADGRA1 | c.1415G>T p.C472F | Missense Mutation (SNP) | VAF 160/242 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ADGRB1 | c.3337G>T p.V1113L | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADGRG4 | c.408C>A p.F136L | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, varscan2
- ADGRG4 | c.567C>G p.D189E | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ADGRG4 | c.5501C>A p.T1834K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ADGRG4 | c.6884G>A p.S2295N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADGRL2 | c.2011G>T p.E671* (on ENST00000370717 / NM_001366005.1; = p.E658* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 47/63 reads (75%) | called by muse, mutect2, varscan2
- ADGRL3 | c.3810C>A p.N1270K (on ENST00000506720 / NM_001322402.2; = p.N1202K on NM_015236.6) | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADGRL3 | c.4578C>A p.Y1526* (on ENST00000506720 / NM_001322402.2; = p.Y1415* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 53/164 reads (32%) | called by muse, mutect2, varscan2
- ADGRV1 | c.485del p.G162Afs*22 | Frame Shift Del (DEL) | VAF 22/43 reads (51%) | called by mutect2, pindel, varscan2
- ADIPOQ | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 66/120 reads (55%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- AFAP1L2 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 64/113 reads (57%) | called by muse, mutect2, varscan2
- AFF2 | c.1769G>C p.S590T | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AFP | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AGBL1 | c.1181A>T p.H394L | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AHCTF1 | c.2046G>C p.E682D (on ENST00000366508; = p.E656D on NM_015446.5) | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- AHNAK | c.14638G>T p.G4880C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK | c.14292del p.N4765Tfs*14 | Frame Shift Del (DEL) | VAF 89/224 reads (40%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.14962C>G p.L4988V | Missense Mutation (SNP) | VAF 144/145 reads (99%) | SIFT tolerated (0.18); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- AHSG | c.970G>T p.V324F | Missense Mutation (SNP) | VAF 129/253 reads (51%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AIFM3 | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 160/529 reads (30%) | called by muse, mutect2, varscan2
- AK5 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- AKAP17A | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 108/108 reads (100%) | called by muse, mutect2, varscan2
- AKR1C1 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKR1C4 | c.860A>C p.Q287P | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ALK | c.4047C>A p.D1349E | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.421); called by muse, varscan2
- ALMS1 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- ALOX12B | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 99/219 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- ALPK1 | c.620dup p.M209Dfs*24 | Frame Shift Ins (INS) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- AMIGO1 | c.1477G>C p.V493L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AMOT | c.3164C>A p.P1055H (on ENST00000371959 / NM_001113490.1; = p.P646H on NM_133265.3) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- AMY2B | c.1220+1G>T p.X407_splice | Splice Site (SNP) | VAF 42/299 reads (14%) | called by muse, mutect2, varscan2
- ANAPC7 | c.1483G>T p.G495* | Nonsense Mutation (SNP) | VAF 56/122 reads (46%) | called by muse, mutect2, varscan2
- ANGEL1 | c.1457del p.G486Afs*41 | Frame Shift Del (DEL) | VAF 62/84 reads (74%) | called by mutect2, pindel, varscan2
- ANK2 | c.3029A>T p.K1010M | Missense Mutation (SNP) | VAF 100/168 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK3 | c.8825G>T p.G2942V | Missense Mutation (SNP) | VAF 52/81 reads (64%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD1 | c.335C>A p.P112H | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ANKRD12 | c.4505C>A p.A1502D | Missense Mutation (SNP) | VAF 79/107 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ANKRD2 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.187); called by muse, varscan2
- ANKRD52 | c.2365T>A p.Y789N | Missense Mutation (SNP) | VAF 111/211 reads (53%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKS1B | c.2284G>T p.A762S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- AP3D1 | c.2256G>C p.K752N | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- APEX2 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 56/56 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APLNR | c.538C>G p.Q180E | Missense Mutation (SNP) | VAF 96/206 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOBR | c.2728G>T p.A910S (on ENST00000431282; = p.A919S on NM_018690.4) | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ARHGAP25 | c.1919A>T p.K640M (on ENST00000409202 / NM_001007231.3; = p.K632M on NM_014882.3) | Missense Mutation (SNP) | VAF 94/275 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- ARHGAP27 | c.2174-7G>T | Splice Region (SNP) | VAF 51/124 reads (41%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.189+1G>T p.X63_splice | Splice Site (SNP) | VAF 160/248 reads (65%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.501+4G>T | Splice Region (SNP) | VAF 99/157 reads (63%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 168/274 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARHGAP40 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 65/180 reads (36%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.2730G>T p.Q910H (on ENST00000337414 / NM_013427.3; = p.Q707H on NM_013423.3) | Missense Mutation (SNP) | VAF 131/132 reads (99%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF12 | c.2522T>C p.L841P | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF15 | c.2111C>A p.P704H | Missense Mutation (SNP) | VAF 151/294 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ARHGEF17 | c.3527G>T p.R1176L | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARHGEF28 | c.4970A>G p.E1657G (on ENST00000426542; = p.E1683G on NM_001080479.2) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF37 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ARID1B | c.6546G>T p.M2182I | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- ARRDC3 | c.1152G>T p.Q384H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARX | c.1074-1G>T p.X358_splice | Splice Site (SNP) | VAF 160/1006 reads (16%) | called by muse, mutect2, varscan2
- ASAP1 | c.2962G>T p.D988Y | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASB10 | c.620T>A p.V207E (on ENST00000420175 / NM_001142459.2; = p.V192E on NM_080871.4) | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASCC3 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- ASRGL1 | c.749T>A p.L250Q | Missense Mutation (SNP) | VAF 176/331 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ATG2A | c.3530G>T p.R1177L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- ATG4A | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ATL3 | c.287dup p.L96Ffs*3 | Frame Shift Ins (INS) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- ATN1 | c.2500G>T p.E834* | Nonsense Mutation (SNP) | VAF 165/235 reads (70%) | called by muse, mutect2, varscan2
- ATP11C | c.3304C>A p.L1102M | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ATP12A | c.2930A>C p.Q977P | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP1A3 | c.2662G>A p.G888S (on ENST00000545399 / NM_001256214.2; = p.G875S on NM_152296.5) | Missense Mutation (SNP) | VAF 350/619 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ATP1A4 | c.1699C>A p.L567M | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- ATP2A1 | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 107/183 reads (58%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP2B3 | c.1802C>A p.A601D | Missense Mutation (SNP) | VAF 104/205 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
2,118 further variants in this file (1,221 protein-altering or splice-affecting, 557 silent, 340 other) are not listed here.
